Somatic mutation profile of tumor specimen MP2PRT-PAUBZC-TMP1-A (aliquot MP2PRT-PAUBZC-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUBZC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,015 days).
Specimen MP2PRT-PAUBZC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea5c7454-a901-4200-a658-fded77012e59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBZC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBZC-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a9b5fe6-9f28-45c5-ba2e-6ff234f7ea38

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNTL1 | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 323/810 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs201021215, COSV57949021; called by muse, mutect2, varscan2
- HSPA12A | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 30/818 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs782030204; called by muse, mutect2
- NR1I2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 210/806 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs772838074, COSV61977003; called by muse, mutect2, varscan2
- NUAK2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 376/941 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571070763; called by muse, mutect2, varscan2
- OR10C1 | c.194G>A p.R65H (on ENST00000622521; = p.R63H on NM_013941.3) | Missense Mutation (SNP) | VAF 95/1610 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as rs779708085, COSV65823122, COSV65823353; called by muse, mutect2
- SPDYE4 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 230/1059 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771206700, COSV60905588; called by muse, mutect2, varscan2
- VCAN | c.9563G>A p.R3188H | Missense Mutation (SNP) | VAF 50/988 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917249805, COSV54109411, COSV54115967; called by muse, mutect2
- ABCD2 | c.1838A>T p.E613V | Missense Mutation (SNP) | VAF 232/545 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAT1 | c.597T>A p.N199K | Missense Mutation (SNP) | VAF 184/445 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.171); called by muse, varscan2
- ADAMTS9 | c.2608A>T p.I870F | Missense Mutation (SNP) | VAF 336/763 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ATP1A4 | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 22/799 reads (3%) | called by muse, mutect2
- COL4A3 | c.3724G>T p.G1242C | Missense Mutation (SNP) | VAF 30/722 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDC4 | c.237C>T p.V79= | Splice Region (SNP) | VAF 14/505 reads (3%) | called by muse, mutect2
- IGHV4-61 | c.351_356delinsTTTGAGGAAGG p.R118Lfs*? | Frame Shift Ins (INS) | VAF 37/429 reads (9%) | called by pindel, varscan2*
- KIF18A | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 203/470 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRLR | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 21/712 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); called by muse, mutect2
- ZMYM2 | c.3903A>T p.R1301S | Missense Mutation (SNP) | VAF 193/412 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PHYKPL | c.369G>A p.L123= | Silent (SNP) | VAF 366/825 reads (44%) | called by muse, mutect2, varscan2
- TBXT | c.1140C>T p.P380= | Silent (SNP) | VAF 640/1478 reads (43%) | catalogued as rs763303937, COSV99752171; called by muse, mutect2
